Surgical pathology report (de-identified scan), TCGA case TCGA-KM-A7Q8, project TCGA-KICH (Kidney Chromophobe), tissue source site NCI Urologic Oncology Branch, specimen TCGA-KM-A7Q8-01B (Primary Tumor).

[page 1 of 4]
Patient Results

Page 1 of 4

Gender: Male	Birth Date:	Admit Date:
Attending:	Admit Protocol:	Age:
		Location:

Surgical Pathology [OrderID:]	Final Results
--------------------------------	---------------

Surgical Pathology

Final

CASE NUMBER:

DIAGNOSIS:

1. Lymph nodes, periaortic, resection: Metastatic Renal cell carcinoma in lymph nodes; (2/40).
2. Kidney, left, nephrectomy: Renal parenchyma with chronic interstitial nephritis; no tumor seen. Vascular and ureteral margins are free of tumor.
3. Left kidney tumor mass, resection: Renal cell carcinoma, chromophobe type with diffuse spindle cell (sarcomatoid) component. Tumor permeates the capsule. Extensive vascular invasion present. See Note.
4. Lymph nodes, hilar, resection: One of ten lymph nodes involved by tumor (1/10)

ICD-O-3
Carcinoma, renal cell
Chromophobe Type 8317/3
Site: @ Kidney NOS C64.9
J5924/13

NOTE: Metastatic involvement by tumor is seen diffusely in the lymphatics present in the fibroadipose tissue.

Surgical Pathology Cancer Case Summary
KIDNEY: Nephrectomy

Procedure: Radical nephrectomy

Specimen Laterality: Left

Tumor Size: Greatest dimension: 20 cm

Tumor Focality: unifocal

Macroscopic Extent of Tumor: Tumor extension into perinephric tissues

Histologic Type: Chromophobe renal cell carcinoma

Sarcomatoid Features: Present

Specify percentage of sarcomatoid element: 50%

Tumor Necrosis: Present

Histologic Grade: Not applicable

Microscopic Tumor Extension: Tumor extension into perinephric tissue (beyond renal capsule)

Margins: vascular and ureteral margins uninvolved by carcinoma

Lymph-Vascular Invasion (excluding renal vein and its muscle containing segmental branches and inferior vena cava): Present

Pathologic Staging (pTNM)

Confidential Patient Information. Unauthorized disclosure is prohibited by the Federal Privacy Act of 1974.

JobID:

Requested By:

Do not file in Medical Record

[page 2 of 4]
Gender: Male		Birth Date:	Admit Protocol:
Admit Protocol:		Admit Protocol:	Age:
			Location:

Surgical Pathology [OrderID:	Final Results
------------------------------	---------------

pT3: Tumor extends into major veins or perinephric tissues but not into the ipsilateral adrenal gland and not beyond Gerota's fascia
pN1: Metastasis in regional lymph node(s)
Number of Lymph Nodes Examined : 50
Number of Lymph Nodes Involved : 3
Distant Metastasis (pM): Not applicable

Pathologic Findings in Nonneoplastic Kidney: chronic interstitial nephritis

Immunoperoxidase and in-situ hybridization tests performed here and used for diagnosis were developed and their performance characteristics determined by the . They have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has also determined that such clearance or approval is not necessary. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing.

CLINICAL INFORMATION: Brief Clinical History: Large left renal mass
Specimen Taken For
Protocol: 01 - Yes Allocate Order to Protocol:

PROCEDURE: Pre-Operative Diagnosis: Renal cell carcinoma
Post-Operative
Diagnosis: same Operative Findings: Large renal mass, kidney removed

SPECIMENS SUBMITTED: 1. PERIAORTIC LYMPH NODE
2. KIDNEY, LEFT
3. TUMOR, Left kidney
4. HILAR LYMPH NODE

GROSS DESCRIPTION: Received are 3 specimens fresh in containers labeled with the patient's name, medical record number, and further specified as follows:

1. "Periaortic lymph nodes". The specimen consists of tan-yellow fragments of fatty-appearing soft tissue measuring approximately 7 cm x 6.5 cm x 2 cm. The specimen is sectioned and entirely submitted in white cassettes 1A-1P. 1 C is 1 lymph node bisected. 1E is 1 lymph node bisected.
2. "Left kidney". The specimen consists of a kidney measuring 15.5 cm x 6.5 cm x 4.5 cm. The resection margin is 14 x 6 cm. Attached fatty tissue is 26 x 19 x 2 cm. Gross photographs are taken. Approximately 3 x 2 x 0.5 cm of tissue is procured for
Remainder of the specimen is placed into formalin and submitted to

[page 3 of 4]
Gender: Male	Birth Date:	Admit Protocol:
Admit Protocol:	Admit Protocol:	Age:
		Location:

Surgical Pathology [OrderID: _____]

Final Results

pathology for permanent processing. Procurement was performed by _____ and _____ on _____

at _____ The remaining specimen is submitted to Pathology for permanent processing. The specimen is received in Surgical Pathology and matches the above description. The fatty tissue is sealed off and structure resembling the ureter is identified. The pelvis is grossly distorted (this is where the tumor was at the hilum of the kidney). Representative sections are placed as follows:

2A - possible ureter and vascular margins.

2B - representative sections of kidney parenchyma from the pelvis.

2C - representative sections of kidney parenchyma from the cortex.

2D-2F: possible lymph nodes.

2G-2P: Additional sections of specimen #2

3. "Left kidney tumor". The specimen measures overall 20 x 15.5 x 12 cm. The specimen weighs approximately 1,600 grams. The external surface of the mass was inked in black prior to cutting it open for procurement. Cut surface is variegated and appears to be hemorrhagic and necrotic and cystic. Approximately 3 cm x 2 cm x 1 cm of tissue was procured for _____ by _____ and Dr. _____ on _____ at _____. Specimen is received in surgical pathology and matches the above description. Representative sections of the tumor are placed in white cassettes. Additional sections of tumor are placed in green cassettes.

4. "Hilar lymph nodes". The specimen consists of tan-yellow fatty-appearing tissue measuring approximately 4.5 cm x 3 cm x 1 cm. The specimen is sectioned and entirely submitted in white cassettes. -4I. 4A is 1 lymph node bisected. 4B is 1 lymph node bisected.

Gross Description dictated by _____ on _____ Additional Gross Description dictated by _____ on _____ Additional Gross Description dictated by _____ on _____

No consultants

Accessioned:

Final Report Signed Out:

<Resident Signature>

M.D. Clinical Resident

<Sign Out Dr. Signature>

ATTENDING STAFF PATHOLOGIST

Confidential Patient Information. Unauthorized disclosure is prohibited by the Federal Privacy Act of 1974.

JobID: _____

Requested By: _____

Do not file in Medical Record

[page 4 of 4]
Gender: Male	Birth Date:	Admit Protocol:
Admit Protocol:	Admit Protocol:	Location:

Surgical Pathology [OrderID: _____]	Final Results
-------------------------------------	---------------

Date Report Signed:

Criteria	W 9/14/13	Yes	No

Confidential Patient Information. Unauthorized disclosure is prohibited by the Federal Privacy Act of 1974.

JobID:

Requested By:

Do not file in Medical Record

Source: NCI Genomic Data Commons file f056e2f7-d6e3-4692-b812-dbb2fcc46de7 (TCGA-KM-A7Q8.FC0B979B-314A-487D-9BBB-E6F8BE3C4E62.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).